Somatic mutation profile of tumor specimen TCGA-VQ-A8PX-01A (aliquot TCGA-VQ-A8PX-01A-12D-A410-08) from TCGA case TCGA-VQ-A8PX, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 51.8 years (18,902 days).
Specimen TCGA-VQ-A8PX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c3102dc-05fa-4c20-b0cc-d648cdabf1a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PX-10A (Blood Derived Normal), aliquot TCGA-VQ-A8PX-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3224c830-5ee7-42da-946b-35d91e5f0ac3

The open-access MAF lists 702 somatic variants for this specimen: 512 protein-altering or splice-affecting, 171 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 341, Silent 171, Frame Shift Del 117, Frame Shift Ins 21, Splice Site 14, Nonsense Mutation 9, In Frame Del 7, RNA 5, Intron 4, 3'UTR 4, Splice Region 3, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CENPF | c.5920del p.T1974Pfs*11 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | catalogued as rs757531591; ClinVar: pathogenic; called by mutect2, varscan2
- FKTN | c.1106del p.F369Sfs*37 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs750176716; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- HNF1B | c.1561del p.Q521Sfs*70 | Frame Shift Del (DEL) | VAF 17/39 reads (44%) | catalogued as rs764042837; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- MLH1 | c.677+1G>A p.X226_splice | Splice Site (SNP) | VAF 10/28 reads (36%) | catalogued as rs267607778, CD962070, CS023479, CS042554, COSV99212286; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIGV | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149690056; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC6A1 | c.1328dup p.X443_splice | Splice Site (INS) | VAF 42/129 reads (33%) | catalogued as rs1199489242; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- TOP3A | c.2271del p.R758Gfs*15 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | catalogued as rs752838075; ClinVar: pathogenic; called by pindel, varscan2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 26/58 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.611del p.L204Cfs*24 | Frame Shift Del (DEL) | VAF 15/121 reads (12%) | catalogued as rs773808328; called by mutect2, pindel, varscan2
- AC244197.3 | c.827T>C p.I276T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100557761; called by muse, mutect2, varscan2
- ACAN | c.6394A>C p.T2132P | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.891); catalogued as COSV100716649; called by muse, mutect2, varscan2
- ADAMTS2 | c.2210-2del p.X737_splice | Splice Site (DEL) | VAF 6/36 reads (17%) | catalogued as rs1219329381; called by mutect2, pindel, varscan2
- ADAMTS4 | c.2501C>T p.A834V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs114600134, COSV63489609, COSV63491343; called by muse, mutect2, varscan2
- AJUBA | c.1190A>G p.Q397R | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV52986984; called by muse, mutect2
- AMBN | c.266T>C p.M89T | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV100534209; called by muse, mutect2
- AMOT | c.2025A>C p.E675D (on ENST00000371959 / NM_001113490.1; = p.E266D on NM_133265.3) | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV100494647; called by muse, mutect2, varscan2
- ANKMY1 | c.305T>G p.L102R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99800893; called by muse, mutect2, varscan2
- ANKRD11 | c.7391A>G p.Q2464R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99967851; called by muse, varscan2
- ANKRD6 | c.2016del p.F672Lfs*34 (on ENST00000339746 / NM_001242809.2; = p.F667Lfs*34 on NM_014942.4) | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as rs751514998, COSV100329734; called by mutect2, pindel, varscan2
- ANO2 | c.2251T>C p.F751L (on ENST00000356134 / NM_001278597.3; = p.F755L on NM_001278596.3) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100499314; called by muse, mutect2
- ANO3 | c.2638G>A p.G880R | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.875); catalogued as COSV99879604, COSV99884225; called by muse, mutect2, varscan2
- ANXA6 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100636739; called by muse, mutect2, varscan2
- AOC1 | c.2222del p.P741Lfs*54 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs999461756; called by mutect2, pindel, varscan2
- AP3B1 | c.2761G>A p.E921K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs1283996817; called by muse, mutect2, varscan2
- ARFGEF3 | c.1386G>T p.K462N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV52475635; called by muse, mutect2
- ARHGAP9 | c.2045A>G p.H682R (on ENST00000393797 / NM_001319850.2; = p.H663R on NM_032496.4) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs577648313, COSV99953509; called by muse, mutect2, varscan2
- ARMC9 | c.1550A>T p.E517V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV100589397; called by muse, mutect2
- ARMH4 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.104); catalogued as COSV99957394; called by muse, mutect2, varscan2
- ARPP21 | c.1619A>G p.Q540R | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.3); PolyPhen benign (0.046); catalogued as COSV99490394; called by muse, mutect2, varscan2
- ASCC3 | c.4110C>A p.Y1370* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100976129; called by muse, mutect2
- ASIC5 | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.145); catalogued as COSV101611094; called by muse, mutect2, varscan2
- ASXL1 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745960978, COSV100037191; called by muse, mutect2, varscan2
- ATF7 | c.679C>T p.P227S (on ENST00000548446 / NM_001366555.2; = p.P216S on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as COSV100129028, COSV100129197; called by muse, mutect2, varscan2
- ATP10A | c.996A>G p.I332M | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs1391278793, COSV100790639; called by muse, mutect2, varscan2
- ATP2A1 | c.1712del p.P571Rfs*21 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs772363145; called by mutect2, pindel, varscan2
- ATP6V1C1 | c.566T>C p.V189A | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV101214750; called by muse, mutect2
- BAG6 | c.1078A>G p.T360A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99276169; called by muse, mutect2, varscan2
- BOC | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as rs137964032; called by muse, mutect2, varscan2
- BPGM | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as COSV100790142; called by muse, mutect2
- BTN1A1 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs754677050, COSV99764063; called by muse, mutect2, varscan2
- C19orf44 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs774156051, COSV99684832; called by muse, mutect2, varscan2
- C2orf78 | c.2668C>T p.R890C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs947815971, COSV101280875, COSV101280955; called by muse, mutect2, varscan2
- C3orf20 | c.2368A>G p.K790E | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs751432931, COSV99513224; called by muse, mutect2, varscan2
- CACNB1 | c.671A>G p.D224G | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100703253; called by muse, mutect2
- CACNB3 | c.492+2T>C p.X164_splice | Splice Site (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99974553; called by muse, mutect2, varscan2
- CALHM2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs756784159, COSV53298020; called by mutect2, varscan2
- CARD14 | c.2759C>A p.P920H | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100413245; called by muse, mutect2
- CARMIL2 | c.130C>T p.L44= | Splice Region (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100575888; called by muse, mutect2, varscan2
- CARS2 | c.571+2T>C p.X191_splice | Splice Site (SNP) | VAF 26/226 reads (12%) | catalogued as rs749363417, COSV99959286; called by muse, mutect2, varscan2
- CBL | c.2189C>T p.T730M | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as rs376848406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCR8 | c.326T>G p.V109G | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100412986; called by muse, mutect2, varscan2
- CDC6 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99266458; called by muse, mutect2, varscan2
- CDH1 | c.2326C>A p.L776M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99930953; called by muse, mutect2, varscan2
- CDH2 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs201148355, COSV52293905; called by muse, mutect2, varscan2
- CDH3 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs374865506; called by muse, mutect2, varscan2
- CDHR2 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs950111037, COSV99990819; called by muse, mutect2, varscan2
- CERS4 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 14/98 reads (14%) | catalogued as rs932198588, COSV52171138; called by muse, mutect2, varscan2
- CFAP61 | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV55629786, COSV99842414; called by muse, mutect2, varscan2
- CHD3 | c.1535T>A p.I512N | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100390449; called by muse, mutect2, varscan2
- CHD6 | c.2482C>T p.R828* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100497535; called by muse, mutect2, varscan2
- CHEK1 | c.1233+2T>C p.X411_splice | Splice Site (SNP) | VAF 23/58 reads (40%) | catalogued as COSV99629366; called by muse, mutect2, varscan2
- CHRD | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs186990063, COSV52605564; called by muse, mutect2, varscan2
- CHRDL2 | c.607A>G p.S203G | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99733409; called by muse, mutect2
- CHRNA4 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as rs1358386465, COSV64718497; called by muse, mutect2, varscan2
- CHRNA6 | c.833T>C p.V278A | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99372978; called by muse, mutect2, varscan2
- CLDN16 | c.331T>C p.Y111H | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs567783618, COSV99289880; called by muse, mutect2, varscan2
- CLHC1 | c.1582A>G p.M528V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV101284776; called by muse, mutect2, varscan2
- CNGA4 | c.1384A>G p.T462A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV101171698; called by muse, mutect2, varscan2
- CNTNAP1 | c.2774G>A p.R925H | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); catalogued as rs779511124, COSV99225976; called by muse, mutect2, varscan2
- COL12A1 | c.4087T>C p.S1363P | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV100485075; called by muse, mutect2
- COL6A6 | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760929088, COSV62040954; called by muse, mutect2, varscan2
- CPXM2 | c.2023G>A p.D675N | Missense Mutation (SNP) | VAF 131/211 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs747926025, COSV53867539, COSV99580593; called by muse, mutect2, varscan2
- CREB5 | c.1100G>A p.R367Q (on ENST00000357727 / NM_182898.4; = p.R360Q on NM_004904.3) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV63227742; called by muse, mutect2, varscan2
- CRMP1 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs1450790289, COSV61478375; called by muse, mutect2, varscan2
- CRYBB3 | c.14A>G p.H5R | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs779636937, COSV99308936; called by muse, mutect2, varscan2
- CSMD3 | c.7955C>T p.T2652M (on ENST00000297405 / NM_001363185.1; = p.T2548M on NM_052900.3) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757060591, COSV52186438, COSV52276704, COSV99835151; called by muse, mutect2
- CSMD3 | c.3892G>A p.D1298N (on ENST00000297405 / NM_001363185.1; = p.D1194N on NM_052900.3) | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV52214246, COSV52362649; called by muse, mutect2
- CSTL1 | c.16T>C p.W6R | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV99851034; called by mutect2, varscan2
- CUBN | c.3562A>G p.S1188G | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.503); catalogued as COSV100911752; called by muse, mutect2, varscan2
- CUEDC1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as rs769636977, COSV100804616; called by muse, mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | catalogued as rs745836350; called by mutect2, varscan2
- CYP26B1 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1286205679, COSV99134148; called by muse, mutect2, varscan2
- CYP4F22 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.746); catalogued as rs146689227, COSV54108972; called by muse, mutect2, varscan2
- CZIB | c.170del p.G57Afs*23 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs760163030; called by mutect2, pindel, varscan2
- DCAF8 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as COSV100470015; called by muse, mutect2, varscan2
- DCST1 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55057769, COSV99792536; called by muse, mutect2, varscan2
- DDR1 | c.543G>T p.E181D | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100240790; called by muse, mutect2, varscan2
- DDX55 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as rs1351655990, COSV99434058; called by muse, mutect2, varscan2
- DENND2B | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as rs1312707636, COSV58206280; called by muse, mutect2
- DENND3 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as rs777091716, COSV52802905; called by muse, mutect2, varscan2
- DENND4C | c.4288G>A p.A1430T (on ENST00000434457 / NM_001330640.2; = p.A1381T on NM_017925.7) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV100727264; called by muse, mutect2, varscan2
- DERL1 | c.671del p.P224Lfs*4 | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | catalogued as rs1314875568; called by mutect2, pindel, varscan2
- DGKK | c.3101C>T p.T1034I | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV101052834; called by muse, mutect2, varscan2
- DHFR2 | c.164G>T p.R55M | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs749911929, COSV100113003; called by muse, mutect2, varscan2
- DHRS7B | c.309+1G>T p.X103_splice | Splice Site (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100683834; called by muse, mutect2, varscan2
- DLL3 | c.746del p.T249Rfs*63 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as COSV52693801; called by mutect2, pindel, varscan2
- DLL3 | c.1824del p.Y610Tfs*8 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as COSV52693492; called by mutect2, pindel
- DMD | c.3175A>G p.T1059A | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as rs763548540, COSV100817134; called by muse, mutect2, varscan2
- DMP1 | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377414504, COSV99218381; called by muse, mutect2
- DMXL1 | c.8902A>G p.S2968G | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100222893; called by muse, mutect2, varscan2
- DNAH1 | c.6232T>C p.F2078L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101324255; called by muse, mutect2, varscan2
- DNAH5 | c.5003G>A p.R1668Q | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs867205765, COSV54203168; called by muse, mutect2, varscan2
- DOK6 | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs764634905, COSV66927909; called by muse, mutect2, varscan2
- DYRK2 | c.899C>T p.T300M (on ENST00000344096 / NM_006482.3; = p.T227M on NM_003583.4) | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs575789813, COSV100165144; called by muse, mutect2, varscan2
- EGF | c.1342A>G p.S448G | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99490255; called by muse, mutect2, varscan2
- EGF | c.2539A>G p.I847V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1251287116, COSV99490259; called by muse, mutect2, varscan2
- EGFR | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.731); catalogued as rs759106015, COSV99285314; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EHMT2 | c.3056A>G p.Q1019R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.232); catalogued as COSV99998453; called by muse, mutect2
- EIF4G3 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99942736; called by muse, mutect2, varscan2
- ENPP1 | c.1022A>G p.N341S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.491); catalogued as COSV100719273; called by muse, mutect2
- EPHX1 | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.497); catalogued as rs1420985615, COSV64765863; called by muse, mutect2, varscan2
- ERBIN | c.2283T>A p.D761E | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as COSV52329325; called by muse, mutect2
- ERICH6 | c.1626G>T p.L542F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99901257; called by muse, mutect2
- EXOC4 | c.1994G>T p.R665M | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV99551795; called by muse, mutect2, varscan2
- FAM120B | c.2222C>T p.A741V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775606266, COSV99378764; called by muse, mutect2, varscan2
- FAM83D | c.1543del p.H515Tfs*6 | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | catalogued as rs754952124; called by mutect2, pindel, varscan2
- FAM83H | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782737425, COSV101186902; called by muse, mutect2
- FEM1C | c.778del p.R260Efs*7 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | catalogued as rs1561556190; called by mutect2, pindel, varscan2
- FER1L6 | c.2546C>T p.P849L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1022974770, COSV101205212; called by muse, mutect2
- FEZ2 | c.854del p.N285Mfs*19 | Frame Shift Del (DEL) | VAF 30/162 reads (19%) | catalogued as rs772264399; called by mutect2, pindel, varscan2
- FGF7 | c.535del p.T179Rfs*15 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as rs777372807; called by mutect2, varscan2
- FITM1 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs150217465; called by muse, mutect2, varscan2
- FKBP7 | c.339A>G p.I113M | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99247335; called by muse, mutect2, varscan2
- FLT3 | c.2963C>A p.A988D | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV99606822; called by muse, mutect2, varscan2
- FOXN2 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100488883; called by muse, mutect2, varscan2
- FOXO3 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749629630, COSV100669429; called by muse, mutect2, varscan2
- FRMPD3 | c.2485A>G p.T829A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99345359; called by muse, mutect2, varscan2
- GABRR2 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101298774; called by muse, mutect2
- GALNT14 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367671327; called by muse, mutect2
- GATAD2A | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99389405; called by muse, mutect2, varscan2
- GC | c.1121A>G p.E374G | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV99909278; called by muse, mutect2
- GEMIN4 | c.2170G>C p.D724H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100021047; called by muse, varscan2
- GEMIN4 | c.2100C>A p.S700R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100021048; called by muse, varscan2
- GGCX | c.1556T>C p.I519T | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV99289538; called by muse, mutect2, varscan2
- GJC1 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as rs753057256, COSV57911321; called by muse, mutect2, varscan2
- GLCE | c.992C>A p.A331D | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV99961990; called by muse, mutect2, varscan2
- GLI3 | c.1415A>G p.Q472R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV101229654; called by muse, mutect2, varscan2
- GNA14 | c.448T>C p.S150P | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV100502377; called by muse, mutect2, varscan2
- GNB1 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101060718, COSV66101380; called by mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 16/116 reads (14%) | catalogued as rs370114090; called by mutect2, varscan2
- GPR12 | c.11A>G p.D4G | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV67344734; called by mutect2, varscan2
- GPR87 | c.271A>C p.T91P | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99608608; called by muse, mutect2, varscan2
- GRK3 | c.1282T>G p.L428V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV100150852; called by muse, mutect2, varscan2
- GUCY2C | c.2489T>C p.I830T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760711995, COSV99663059; called by muse, mutect2, varscan2
- HAUS3 | c.41T>A p.I14N | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54723786, COSV99704068; called by mutect2, varscan2
- HCAR2 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.861); catalogued as rs771062373, COSV61025586; called by muse, mutect2, varscan2
- HEXB | c.1298T>C p.L433P | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99713898; called by muse, mutect2, varscan2
- HEXIM2 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.436); catalogued as COSV56235977; called by muse, mutect2
- HIF1AN | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.123); catalogued as rs777658624, COSV100142497; called by muse, mutect2, varscan2
- HOMEZ | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761393545, COSV100663989; called by muse, mutect2, varscan2
- HOOK2 | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as COSV99317249; called by muse, mutect2, varscan2
- HOXC6 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99678879; called by muse, mutect2, varscan2
- HOXD3 | c.910A>G p.K304E | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs774077828, COSV99979791; called by muse, mutect2, varscan2
- HSD17B4 | c.2070T>C p.T690= (on ENST00000414835 / NM_001199291.3; = p.T665= on NM_000414.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 12/45 reads (27%) | catalogued as COSV99819348; called by muse, mutect2, varscan2
- HSPA12A | c.1388T>C p.L463P | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV100979689; called by muse, mutect2
- HTR2C | c.587A>G p.D196G | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV99347645; called by muse, mutect2, varscan2
- IARS1 | c.3177G>T p.Q1059H | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV100986666, COSV100986672; called by muse, mutect2, varscan2
- IKBKB | c.1445A>C p.K482T | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV100645538; called by muse, mutect2
- IKZF4 | c.134A>G p.Q45R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV100008795; called by muse, mutect2
- IL13 | c.374T>C p.V125A | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs777911950, COSV100449368; called by mutect2, varscan2
- IL16 | c.2780G>A p.R927Q (on ENST00000302987 / NM_172217.5; = p.R226Q on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs750738616, COSV57260733; called by muse, mutect2, varscan2
- IL1A | c.47+2T>C p.X16_splice | Splice Site (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99641216; called by muse, varscan2
- ILDR2 | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV99612935; called by muse, mutect2, varscan2
- ILF3 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1476198467, COSV51562766; called by muse, mutect2, varscan2
- IMPA2 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs140100753; called by muse, mutect2, varscan2
- IPO7 | c.2496T>G p.H832Q | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101121750; called by muse, mutect2, varscan2
- IQCC | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.676); catalogued as rs373839136; called by muse, mutect2, varscan2
- ITGB3BP | c.476C>A p.P159H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV99370674; called by muse, mutect2, varscan2
- ITLN2 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as rs368397499; called by muse, mutect2, varscan2
- JAKMIP2 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54599749; called by muse, mutect2, varscan2
- JCHAIN | c.164T>C p.I55T | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs199752258; called by muse, mutect2, varscan2
- JHY | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs1450781444, COSV56219522; called by muse, mutect2, varscan2
- KANK4 | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100586899; called by muse, mutect2, varscan2
- KAT6A | c.4183G>A p.D1395N | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV55909851; called by muse, mutect2
- KCNC1 | c.911A>T p.K304M | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99788518; called by muse, mutect2
- KCNG4 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.772); catalogued as rs752116605, COSV57583577; called by muse, mutect2, varscan2
- KCNH8 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as COSV100107935, COSV60472395; called by muse, mutect2, varscan2
- KCNQ2 | c.1478G>A p.R493H (on ENST00000359125 / NM_172107.4; = p.R465H on NM_004518.6) | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs774040213, COSV60544845; called by muse, mutect2, varscan2
- KCNU1 | c.3112C>A p.P1038T | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs946025344, COSV101298683; called by muse, mutect2, varscan2
- KDM5D | c.1462A>G p.K488E | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100522116; called by muse, mutect2, varscan2
- KIAA1549 | c.3871T>C p.S1291P | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as COSV54313629; called by muse, mutect2
- KIF5B | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs201506716, COSV56652649; called by muse, mutect2, varscan2
- KIRREL3 | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.356); catalogued as COSV101585502; called by muse, mutect2, varscan2
- KLK9 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99143858; called by muse, mutect2, varscan2
- KMT2A | c.5539C>T p.P1847S | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as COSV100627462; called by muse, mutect2, varscan2
- KRTAP5-1 | c.263del p.G88Afs*? | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | catalogued as rs1554942480, COSV101192918; called by mutect2, pindel, varscan2
- KTI12 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs756161230, COSV100860117; called by muse, mutect2, varscan2
- LIPK | c.554A>C p.N185T | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.907); catalogued as COSV101344931; called by muse, mutect2, varscan2
- LRIG3 | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772953918, COSV57867902; called by muse, mutect2, varscan2
- LRP1B | c.6420A>C p.R2140S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101249278; called by muse, mutect2, varscan2
- LRRC8C | c.1524del p.W509Gfs*13 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | catalogued as rs762972819; called by mutect2, pindel, varscan2
- LRRK1 | c.5131C>T p.P1711S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs1316190212, COSV99436803; called by muse, mutect2, varscan2
- MACC1 | c.1270T>G p.S424A | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV100255097; called by muse, mutect2
- MACF1 | c.9641A>G p.D3214G | Missense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as rs1224243389, COSV57112617; called by muse, mutect2, varscan2
- MAGED2 | c.1355G>T p.S452I | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99514319; called by muse, mutect2
- MAGI1 | c.1133T>C p.V378A | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs761124349, COSV100438780; called by muse, mutect2, varscan2
- MAML2 | c.2543T>C p.L848P | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as COSV101593907; called by muse, mutect2
- MAOA | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100108478; called by muse, mutect2, varscan2
- MAPK15 | c.1576G>T p.G526W | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100567629; called by muse, mutect2, varscan2
- MATN3 | c.1159del p.T387Hfs*10 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | catalogued as rs1203662025; called by mutect2, pindel, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MECP2 | c.232T>G p.S78A | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100317710; called by muse, mutect2, varscan2
- MEPCE | c.1612del p.Q538Kfs*52 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | catalogued as COSV99439884; called by mutect2, pindel, varscan2
- MIA2 | c.1089del p.D364Tfs*8 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs538500709; called by mutect2, varscan2
- MMS22L | c.1214A>T p.Y405F | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV99245795; called by muse, mutect2, varscan2
- MOB3C | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs529251316, COSV99596109; called by muse, mutect2, varscan2
- MRGPRD | c.557T>C p.I186T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.268); catalogued as COSV100482881; called by muse, mutect2
- MRPL50 | c.254A>T p.N85I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV100879778; called by muse, mutect2, varscan2
- MTCH1 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753484837, COSV65320604; called by muse, mutect2, varscan2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs759847587; called by mutect2, varscan2
- MTR | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV100855150; called by muse, mutect2
- MUC17 | c.11809A>G p.T3937A | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); catalogued as COSV100070964; called by muse, mutect2, varscan2
- MUC6 | c.3407C>T p.T1136M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs373492122; called by muse, mutect2, varscan2
- MYCN | c.134dup p.E47Gfs*8 | Frame Shift Ins (INS) | VAF 9/22 reads (41%) | catalogued as rs780080562; called by mutect2, varscan2
- MYOF | c.4130T>C p.V1377A | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100824985; called by muse, mutect2
- MYOZ3 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV51740008; called by muse, mutect2
- NAA16 | c.887T>C p.L296S | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV101038166; called by muse, mutect2, varscan2
- NAALADL1 | c.723dup p.S242Lfs*56 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | catalogued as rs761671591; called by pindel, varscan2
- NAPA | c.841C>A p.L281M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99645556; called by mutect2, varscan2
- NBPF20 | c.16745A>T p.D5582V (on ENST00000369373; = p.D5143V on NM_001278267.1) | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100978549; called by muse, mutect2, varscan2
- NCKAP5L | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs745826212, COSV60133079; called by muse, mutect2
- NCOR2 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs370196674; called by muse, mutect2, varscan2
- NDC1 | c.205T>C p.Y69H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV99323126; called by muse, mutect2, varscan2
- NDFIP1 | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99550997; called by muse, mutect2
- NDST1 | c.2530T>C p.S844P | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99938548; called by muse, mutect2, varscan2
- NDUFA10 | c.604dup p.H202Pfs*25 | Frame Shift Ins (INS) | VAF 8/61 reads (13%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, varscan2
- NELFE | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100963695; called by muse, mutect2
- NELL2 | c.1969A>T p.N657Y | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as COSV100418319; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 22/128 reads (17%) | catalogued as rs759081520; called by mutect2, varscan2
- NIPBL | c.8222C>T p.A2741V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.444); catalogued as COSV99238112; called by muse, mutect2, varscan2
- NNT | c.1238A>G p.D413G | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99238212; called by muse, mutect2, varscan2
- NOA1 | c.1414A>G p.M472V | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs761032181, COSV51736819; called by muse, mutect2, varscan2
- NOTCH4 | c.3610T>C p.S1204P | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV100900245; called by muse, mutect2, varscan2
- NRXN1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as COSV101276076; called by muse, mutect2, varscan2
- NSUN6 | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368955585; called by muse, mutect2, varscan2
- NTN5 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs770023746, COSV54307372; called by muse, mutect2, varscan2
- NTRK1 | c.1049A>C p.Q350P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as COSV100693060, COSV62327196; called by muse, mutect2, varscan2
- NUP205 | c.4772G>A p.R1591H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as rs367553464, COSV99606919; called by muse, mutect2, varscan2
- NUP93 | c.971A>G p.Y324C | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57429213; called by muse, mutect2, varscan2
- NUP98 | c.4190G>A p.R1397H (on ENST00000359171 / NM_001365126.1; = p.R1380H on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/281 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201757730, COSV61428960; called by muse, mutect2
- OPRD1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs990592389, COSV99330006; called by muse, mutect2, varscan2
- OPTN | c.1301A>C p.E434A | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV99537129; called by muse, mutect2, varscan2
- OR10Z1 | c.535del p.C179Vfs*7 | Frame Shift Del (DEL) | VAF 13/126 reads (10%) | catalogued as rs755391413; called by mutect2, pindel, varscan2
- OR1L6 | c.1007G>T p.R336M (on ENST00000373684; = p.R300M on NM_001004453.2) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100490743, COSV59028567, COSV59029142; called by muse, mutect2, varscan2
- OR1Q1 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99939132; called by muse, mutect2, varscan2
- OR2V2 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1318178438, COSV100079962; called by muse, mutect2
- OR6C76 | c.8del p.N3Ifs*5 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | catalogued as rs768848732; called by mutect2, pindel, varscan2
- ORC3 | c.1185+2T>C p.X395_splice | Splice Site (SNP) | VAF 8/55 reads (15%) | catalogued as rs999476290, COSV100005453; called by muse, mutect2, varscan2
- OSBP | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99802436; called by muse, mutect2
- OSBP2 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100212476; called by muse, mutect2, varscan2
- PAPPA2 | c.4454T>C p.F1485S | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV100867361; called by muse, mutect2, varscan2
- PARD3 | c.2418-2A>G p.X806_splice | Splice Site (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100399991; called by muse, mutect2
- PARP14 | c.2683T>C p.Y895H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV101506205; called by muse, mutect2, varscan2
- PCDH12 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV51520347; called by muse, mutect2, varscan2
- PCDHAC1 | c.43T>C p.C15R | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99164852; called by muse, mutect2, varscan2
- PCDHB11 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.826); catalogued as rs1554285402, COSV61310690; called by muse, mutect2, varscan2
- PCDHB13 | c.527A>C p.N176T | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV99506495; called by muse, mutect2, varscan2
- PCDHB15 | c.1006A>G p.K336E | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as rs1554291958, COSV99178793; called by muse, mutect2
- PCDHB3 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV50565386; called by muse, mutect2, varscan2
- PCIF1 | c.1255G>A p.V419M | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs762832749, COSV59818086, COSV59819932; called by muse, mutect2, varscan2
- PCK2 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as rs146891790, COSV99394000; called by muse, mutect2, varscan2
- PCSK2 | c.1333G>A p.G445R | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99358350; called by muse, mutect2
- PDE4D | c.1096G>T p.G366* (on ENST00000340635 / NM_001104631.2; = p.G230* on NM_006203.4) | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV100401249; called by muse, mutect2
- PDK4 | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.087); catalogued as COSV99138697; called by muse, mutect2, varscan2
- PFKFB1 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as rs147665375, COSV100895524; called by muse, mutect2, varscan2
- PHTF1 | c.2075del p.K692Sfs*10 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs752176716, COSV63368077; called by mutect2, pindel
- PIP5K1A | c.698A>G p.Q233R (on ENST00000368888 / NM_001135638.2; = p.Q220R on NM_003557.3) | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV100576423; called by muse, mutect2, varscan2
- PLAG1 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100387623; called by muse, mutect2
- PLEKHF1 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.177); catalogued as rs746887769, COSV71410402; called by muse, mutect2, varscan2
- PLEKHG1 | c.2402A>G p.Q801R | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1562563183, COSV100651388; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100543957; called by muse, mutect2, varscan2
- POLE | c.6676G>A p.G2226R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as rs766291093, COSV100264901, COSV100267841; ClinVar: uncertain significance; called by mutect2, varscan2
- POLR1G | c.653del p.N218Ifs*4 | Frame Shift Del (DEL) | VAF 31/95 reads (33%) | catalogued as rs753626854; called by mutect2, varscan2
- POM121 | c.3659C>T p.A1220V (on ENST00000434423; = p.A955V on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs782004424; called by muse, mutect2, varscan2
- POU4F3 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57942300; called by muse, mutect2
- PPP1R12C | c.1110del p.I373Sfs*51 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | catalogued as COSV54738562; called by mutect2, pindel, varscan2
- PPP1R42 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100220943; called by muse, mutect2, varscan2
- PPP6R1 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV101336903; called by muse, mutect2, varscan2
- PPRC1 | c.4382del p.P1461Hfs*79 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | catalogued as COSV53386648; called by mutect2, pindel, varscan2
- PRAMEF15 | c.1376A>G p.Y459C | Missense Mutation (SNP) | VAF 26/331 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1371371515, COSV65999687; called by muse, varscan2
- PRKAA2 | c.863T>C p.I288T | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV100982725; called by muse, mutect2, varscan2
- PRKAG1 | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV100304788; called by muse, mutect2, varscan2
- PRLHR | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53303905, COSV99492571, COSV99492765; called by muse, mutect2, varscan2
- PROSER3 | c.1262T>C p.V421A | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99994403; called by muse, mutect2, varscan2
- PSD2 | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99216921; called by muse, mutect2
- PTPN13 | c.3436T>C p.S1146P (on ENST00000411767 / NM_080683.3; = p.S1127P on NM_006264.3) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100363779; called by muse, mutect2, varscan2
- PTPRJ | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.055); catalogued as rs899427743, COSV69249671, COSV69255232; called by muse, mutect2
- PTPRR | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150540173; called by muse, mutect2, varscan2
- PTPRS | c.1966G>A p.V656I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.27); catalogued as COSV53638899; called by muse, mutect2, varscan2
- PTPRU | c.2423G>A p.R808H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV60530828; called by muse, mutect2, varscan2
- RABGAP1 | c.1775A>G p.Y592C | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65396416; called by muse, mutect2, varscan2
- RAD54L2 | c.3976T>C p.Y1326H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as COSV99620407; called by muse, mutect2, varscan2
- RADIL | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as rs369420829, COSV101271178; called by muse, mutect2, varscan2
- RBL1 | c.431del p.L144* | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | catalogued as COSV60328025; called by mutect2, pindel
- RBM12B | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as rs370751331; called by muse, mutect2, varscan2
- RBM27 | c.1082T>C p.M361T | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV99505512; called by muse, mutect2, varscan2
- RBM34 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs778495315, COSV100783856; called by mutect2, varscan2
- RBM43 | c.213del p.V72Lfs*13 | Frame Shift Del (DEL) | VAF 29/77 reads (38%) | catalogued as rs746242773; called by mutect2, varscan2
- RC3H2 | c.698A>G p.Q233R | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100106165; called by muse, mutect2, varscan2
- RFC3 | c.871A>G p.I291V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.866); catalogued as COSV101197781; called by muse, mutect2, varscan2
- RHOBTB2 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 76/710 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99310596; called by muse, mutect2, varscan2
- RIOK3 | c.1411T>G p.L471V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs767167541, COSV100259080; called by muse, mutect2, varscan2
- RMDN3 | c.1156del p.T386Lfs*22 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs745408248; called by mutect2, varscan2
- RNF123 | c.1225A>G p.I409V | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs915305696, COSV100570065; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL8 | c.52G>C p.A18P | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99369757, COSV99369985; called by muse, mutect2, varscan2
- RRAGB | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV53329438; called by muse, mutect2
- RRAS2 | c.347A>T p.D116V | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV99818788; called by muse, mutect2, varscan2
- RUVBL1 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.477); catalogued as rs1382834194, COSV100493960; called by muse, mutect2, varscan2
- RYR2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs377368967, COSV63675122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S1PR3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751247905, COSV100822425; called by muse, mutect2, varscan2
- SCARB2 | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99357721; called by muse, mutect2, varscan2
- SCEL | c.692+2T>C p.X231_splice | Splice Site (SNP) | VAF 9/75 reads (12%) | catalogued as rs1377658082, COSV100582448; called by muse, mutect2, varscan2
- SCN9A | c.5766A>C p.R1922S (on ENST00000303354; = p.R1911S on NM_002977.3) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100310666; called by muse, mutect2, varscan2
- SCN9A | c.5339A>G p.E1780G (on ENST00000303354; = p.E1769G on NM_002977.3) | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100310671; called by muse, mutect2, varscan2
- SDAD1 | c.824del p.K275Rfs*15 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | catalogued as rs763181092; called by mutect2, pindel
- SDK1 | c.2353A>C p.I785L | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV101268535, COSV67365706; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SECISBP2L | c.1680del p.G561Efs*9 (on ENST00000559471 / NM_001193489.2; = p.G516Efs*9 on NM_014701.4) | Frame Shift Del (DEL) | VAF 17/113 reads (15%) | catalogued as rs1175119208; called by mutect2, pindel, varscan2
- SEMA4D | c.959T>C p.V320A | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.214); catalogued as COSV100357785; called by muse, mutect2, varscan2
- SERINC1 | c.1322T>G p.L441R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100304972; called by muse, mutect2, varscan2
- SETD6 | c.367del p.V123Cfs*88 (on ENST00000219315 / NM_001160305.4; = p.V99Cfs*88 on NM_024860.3) | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as COSV50747138; called by mutect2, pindel, varscan2
- SGO1 | c.973del p.M325Cfs*28 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | catalogued as rs747473028; called by mutect2, varscan2
- SI | c.887del p.L296* | Frame Shift Del (DEL) | VAF 15/119 reads (13%) | catalogued as rs769103567, COSV52291108; called by mutect2, pindel, varscan2
- SIDT2 | c.2104C>A p.L702M | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV99636808, COSV99638425; called by muse, mutect2, varscan2
- SIPA1L3 | c.3539C>T p.T1180M | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as rs140757614; called by muse, mutect2, varscan2
- SLC17A3 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV100398992; called by muse, mutect2, varscan2
- SLC1A7 | c.1591G>A p.V531I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs753625746, COSV100439245; called by muse, mutect2, varscan2
- SLC22A2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as rs750937051, COSV65265768; called by muse, mutect2, varscan2
- SLC2A14 | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1325643887, COSV61588795; called by muse, mutect2, varscan2
- SLC30A4 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV99970063; called by muse, mutect2, varscan2
- SLC38A8 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100230140; called by muse, mutect2
- SLC44A3 | c.1722del p.F574Lfs*4 (on ENST00000271227 / NM_001114106.3; = p.F526Lfs*4 on NM_152369.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/156 reads (13%) | catalogued as rs752543591, COSV54732637; called by mutect2, pindel, varscan2
- SLC45A4 | c.1033del p.R345Afs*34 (on ENST00000517878 / NM_001286646.2; = p.R294Afs*34 on NM_001080431.2) | Frame Shift Del (DEL) | VAF 17/136 reads (13%) | catalogued as rs768004505; called by mutect2, pindel, varscan2
- SLC4A11 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs748778995, COSV101195857; called by muse, mutect2, varscan2
- SLC66A1 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs771330075, COSV64320852; called by muse, mutect2, varscan2
- SLC9C2 | c.2853C>A p.S951R | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV100876474; called by muse, mutect2, varscan2
- SMARCAD1 | c.2179-2A>G p.X727_splice | Splice Site (SNP) | VAF 13/92 reads (14%) | catalogued as COSV62773568; called by muse, mutect2, varscan2
- SMPD3 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54711543; called by muse, mutect2, varscan2
- SNW1 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774992960, COSV55052903; called by muse, mutect2, varscan2
- SNX4 | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.078); catalogued as COSV99304574; called by muse, mutect2, varscan2
- SPAG1 | c.1037A>G p.N346S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV99308218; called by muse, mutect2, varscan2
- SPATA31D1 | c.3357A>C p.Q1119H | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100782379; called by muse, mutect2, varscan2
- SPIRE2 | c.1259T>A p.M420K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100988670; called by muse, mutect2, varscan2
- SPTAN1 | c.6485T>C p.V2162A | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV100823121; called by muse, mutect2, varscan2
- SPX | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99919482; called by muse, mutect2, varscan2
- SSX2IP | c.1155del p.K385Nfs*4 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | catalogued as COSV60554384; called by mutect2, pindel
- ST13 | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99343879; called by muse, mutect2, varscan2
- STAB1 | c.1726T>C p.Y576H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100400894; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 27/49 reads (55%) | catalogued as rs752994755; called by mutect2, varscan2
- STXBP2 | c.599A>G p.Q200R | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV99656808; called by muse, mutect2
- SUSD1 | c.1273A>C p.M425L | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100813117; called by muse, mutect2, varscan2
- SYCP1 | c.1936T>G p.L646V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV101050695; called by muse, mutect2, varscan2
- SYNE1 | c.16156T>G p.L5386V (on ENST00000367255 / NM_182961.4; = p.L5315V on NM_033071.3) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.886); catalogued as COSV99548973; called by muse, mutect2, varscan2
- SYTL2 | c.2597T>C p.V866A (on ENST00000528231 / NM_001162951.2; = p.V842A on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100313469; called by muse, mutect2, varscan2
- TBK1 | c.976A>G p.I326V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.956); catalogued as COSV100537940; called by muse, mutect2, varscan2
- TCN2 | c.1106+1G>A p.X369_splice | Splice Site (SNP) | VAF 14/54 reads (26%) | catalogued as rs766478911, CS106900, COSV53191548, COSV99308309; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 18/132 reads (14%) | catalogued as rs763321097; called by mutect2, varscan2
- TECPR1 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1327644953, COSV65782750, COSV65785164; called by muse, mutect2
- TECTA | c.3834G>T p.Q1278H | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.365); catalogued as COSV99878094; called by muse, mutect2, varscan2
- TENT5A | c.395A>G p.D132G | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV100198680; called by muse, mutect2, varscan2
- THBS4 | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs760093592, COSV100644153; called by muse, mutect2, varscan2
- THEMIS | c.1218del p.V407Wfs*2 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | catalogued as rs1425728909; called by mutect2, pindel, varscan2
- TINAG | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV52516550; called by muse, mutect2, varscan2
- TMBIM4 | c.520del p.Y174Ifs*4 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs754390908; called by mutect2, varscan2
- TMC2 | c.1391T>A p.V464D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.304); catalogued as COSV100727230; called by muse, mutect2, varscan2
- TMEM151A | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV59174079; called by muse, mutect2
- TOP1MT | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as rs1325634219, COSV61317615; called by muse, mutect2
- TP53 | c.575A>G p.Q192R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.677); catalogued as rs730882002, COSV52839714, COSV53416426; ClinVar: uncertain significance; called by mutect2, varscan2
- TP73 | c.1004del p.P335Lfs*10 | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | catalogued as COSV104414957; called by mutect2, pindel, varscan2
- TPR | c.5092C>T p.R1698C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs764775414, COSV66602562; called by muse, mutect2, varscan2
- TRAPPC9 | c.1495+2T>C p.X499_splice | Splice Site (SNP) | VAF 11/87 reads (13%) | catalogued as COSV101226258; called by muse, mutect2, varscan2
- TRIM31 | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs755255820, COSV100946722; called by muse, mutect2, varscan2
- TRIM32 | c.1817G>A p.G606E | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100523439; called by muse, mutect2, varscan2
- TRIOBP | c.4436del p.G1479Afs*28 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs756145453; called by mutect2, pindel, varscan2
- TRMT2A | c.1411C>T p.R471W | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs201281385, COSV99349656; called by muse, mutect2, varscan2
- TSEN34 | c.764A>G p.H255R | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99824495; called by muse, mutect2, varscan2
- TSHZ2 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.985); catalogued as COSV100295073; called by muse, mutect2
- TTC17 | c.2272A>G p.N758D | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.489); catalogued as COSV99234474, COSV99236063; called by muse, mutect2
- TTC37 | c.131T>G p.V44G | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100706224; called by muse, mutect2
- TULP4 | c.2365G>A p.G789S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs778651745, COSV100892976, COSV65576284; called by muse, mutect2, varscan2
- TWNK | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV99271676; called by muse, mutect2, varscan2
- TYW1 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1016237223, COSV62755636; called by muse, mutect2, varscan2
- UAP1 | c.1507T>C p.F503L (on ENST00000271469 / NM_001324116.1; = p.F486L on NM_003115.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV99617254; called by muse, mutect2, varscan2
- UBXN1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs773227855, COSV53656696; called by muse, mutect2, varscan2
- UGT1A6 | c.1560del p.R522Efs*22 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as COSV59381895; called by mutect2, pindel, varscan2
- UNC13A | c.3386C>T p.T1129M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs953780016, COSV53194995, COSV99406684; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs767420916; called by mutect2, varscan2
- USP2 | c.181A>G p.T61A | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV99489156; called by muse, mutect2, varscan2
- UTP14C | c.134T>A p.L45H | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101584230; called by muse, mutect2, varscan2
- VCAN | c.10107T>A p.N3369K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV99424158; called by muse, mutect2, varscan2
- VGLL3 | c.778G>C p.G260R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV101051841; called by muse, mutect2, varscan2
- VPS13D | c.4277T>C p.I1426T | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99165299; called by muse, mutect2, varscan2
- VPS41 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as rs779846421, COSV100053355; called by muse, mutect2, varscan2
- VPS50 | c.1261A>T p.R421W | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100004335; called by muse, mutect2
- VWA7 | c.1220C>A p.P407H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100991647; called by muse, mutect2, varscan2
- WBP2 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs749493232, COSV99637246; called by muse, mutect2
- WDFY3 | c.1383A>C p.K461N | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99881378; called by muse, mutect2
- WDR1 | c.1585del p.Y529Mfs*26 (on ENST00000382452; = p.Y389Mfs*26 on NM_005112.5) | Frame Shift Del (DEL) | VAF 28/97 reads (29%) | catalogued as rs1451323999, COSV66723865; called by mutect2, pindel, varscan2
- WDR46 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101004689; called by muse, mutect2, varscan2
- WWC3 | c.3049C>T p.R1017W | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757486244, COSV66502408; called by muse, varscan2
- XDH | c.2690G>A p.G897D | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV101051869; called by muse, mutect2, varscan2
- XPC | c.2012G>A p.R671H | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs3731140; called by muse, mutect2, varscan2
- XPNPEP2 | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV100941119; called by muse, mutect2, varscan2
- XPO7 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV53015946; called by muse, mutect2
- ZBP1 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs746334067, COSV59060735; called by muse, mutect2, varscan2
- ZCCHC3 | c.1192A>G p.T398A | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.037); catalogued as COSV101210816; called by muse, mutect2, varscan2
- ZDBF2 | c.5624del p.K1875Rfs*39 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as rs770232797, COSV65623567; called by mutect2, varscan2
- ZFHX4 | c.4837A>T p.R1613W | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99254078; called by muse, mutect2
- ZFP91 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.764); catalogued as rs764585837, COSV100284254; called by muse, mutect2, varscan2
- ZNF112 | c.1840T>C p.C614R (on ENST00000337401 / NM_001083335.2; = p.C608R on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100495397; called by muse, mutect2, varscan2
- ZNF133 | c.195del p.K65Nfs*122 (on ENST00000316358 / NM_001352454.2; = p.K65Nfs*121 on NM_003434.7 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as rs753775995, COSV60366352; called by mutect2, varscan2
- ZNF143 | c.1412C>T p.T471M | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as rs1394297185, COSV55182862; called by muse, mutect2, varscan2
- ZNF219 | c.2157del p.Q720Kfs*28 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as COSV53883789; called by mutect2, pindel, varscan2
- ZNF251 | c.1293A>C p.K431N | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV52957066, COSV99478010; called by muse, mutect2
- ZNF420 | c.1172A>G p.Y391C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1022937994, COSV100421071; called by muse, mutect2, varscan2
- ZNF462 | c.4075T>C p.S1359P | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99470436; called by muse, mutect2, varscan2
- ZNF557 | c.1185del p.K395Nfs*40 (on ENST00000414706 / NM_001044388.2; = p.K402Nfs*40 on NM_024341.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/84 reads (13%) | catalogued as rs759839287; called by mutect2, pindel, varscan2
- ZSCAN31 | c.512T>G p.L171R | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.057); catalogued as COSV100716802; called by muse, mutect2, varscan2
- ZSWIM4 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs771941547, COSV99584361; called by muse, mutect2, varscan2
- ADGRL2 | c.2279_2280del p.K760Rfs*9 (on ENST00000370717 / NM_001366005.1; = p.K747Rfs*9 on NM_012302.4) | Frame Shift Del (DEL) | VAF 69/169 reads (41%) | called by mutect2, pindel, varscan2
- AKAP12 | c.797_798del p.K266Rfs*12 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.7340_7342del p.K2447del | In Frame Del (DEL) | VAF 10/32 reads (31%) | called by pindel, varscan2
- AREG | c.398del p.N133Mfs*30 | Frame Shift Del (DEL) | VAF 68/139 reads (49%) | called by mutect2, pindel, varscan2
- ARID1A | c.4403del p.P1468Lfs*13 | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | called by mutect2, pindel, varscan2
- ARL6IP5 | c.265del p.V89Sfs*5 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- ATAD2 | c.4030del p.S1344Vfs*15 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | called by mutect2, pindel, varscan2
- ATP10D | c.1058del p.F353Sfs*24 | Frame Shift Del (DEL) | VAF 18/156 reads (12%) | called by mutect2, pindel, varscan2
- BICRAL | c.2689del p.T897Qfs*8 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- CC2D2A | c.1438del p.T480Pfs*31 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- CDC27 | c.1456_1459del p.N486Ffs*2 | Frame Shift Del (DEL) | VAF 26/108 reads (24%) | called by mutect2, pindel, varscan2
- CMAS | c.351dup p.D118Rfs*14 | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- CMYA5 | c.12061A>G p.I4021V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- CSTF3 | c.1317del p.K439Nfs*33 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | called by mutect2, pindel, varscan2
- DDX39B | c.447del p.F149Lfs*13 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, varscan2
- DHX16 | c.3097del p.I1033* | Frame Shift Del (DEL) | VAF 10/96 reads (10%) | called by mutect2, pindel
- EGF | c.3160del p.A1054Pfs*25 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel, varscan2
- ENPEP | c.1558dup p.W520Lfs*9 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- EPRS1 | c.4270_4271del p.M1424Gfs*4 | Frame Shift Del (DEL) | VAF 16/128 reads (13%) | called by pindel, varscan2
- FBLIM1 | c.59del p.P20Rfs*11 | Frame Shift Del (DEL) | VAF 46/132 reads (35%) | called by mutect2, pindel, varscan2
- FURIN | c.1339del p.Q447Sfs*25 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by pindel, varscan2
- GLI3 | c.3755del p.P1252Rfs*30 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, varscan2
- GOLGA3 | c.1484del p.N495Mfs*25 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- GRM8 | c.888dup p.L297Tfs*14 | Frame Shift Ins (INS) | VAF 12/74 reads (16%) | called by mutect2, varscan2
- HPS1 | c.870_871del p.E290Dfs*8 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by pindel, varscan2
- HUS1 | c.517dup p.M173Nfs*11 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- IGHV4-59 | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGSF10 | c.6197del p.P2066Qfs*14 | Frame Shift Del (DEL) | VAF 17/128 reads (13%) | called by mutect2, pindel, varscan2
- ILRUN | c.722del p.N241Tfs*29 (on ENST00000374023 / NM_024294.4; = p.N175Tfs*29 on NM_022758.6) | Frame Shift Del (DEL) | VAF 15/83 reads (18%) | called by mutect2, pindel, varscan2
- INTS6 | c.1431del p.V478* | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- JADE1 | c.1180del p.R394Gfs*20 | Frame Shift Del (DEL) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- JAG1 | c.3558del p.N1187Tfs*25 | Frame Shift Del (DEL) | VAF 23/216 reads (11%) | called by mutect2, pindel, varscan2
- MAN2A1 | c.994del p.W332Gfs*17 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | called by mutect2, pindel, varscan2
- MNS1 | c.98del p.N33Tfs*50 | Frame Shift Del (DEL) | VAF 13/152 reads (9%) | called by mutect2, pindel
- MRC1 | c.2436T>G p.Y812* | Nonsense Mutation (SNP) | VAF 13/380 reads (3%) | called by muse, mutect2
- MRC1 | c.2722T>G p.F908V | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.186); called by muse, mutect2
- MYL7 | c.378-3dup | Splice Region (INS) | VAF 8/76 reads (11%) | called by mutect2, pindel, varscan2
- MYO9A | c.5561_5562del p.S1854Cfs*9 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | called by pindel, varscan2
- MYSM1 | c.58del p.A20Hfs*78 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- NCKAP1 | c.2003del p.N668Tfs*5 | Frame Shift Del (DEL) | VAF 35/163 reads (21%) | called by mutect2, pindel, varscan2
- NCKAP5 | c.1253del p.P418Hfs*3 | Frame Shift Del (DEL) | VAF 25/100 reads (25%) | called by mutect2, pindel, varscan2
- NCOA3 | c.1400del p.P467Hfs*15 | Frame Shift Del (DEL) | VAF 24/106 reads (23%) | called by mutect2, pindel, varscan2
- NECTIN3 | c.1416del p.E473Kfs*6 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- NRXN1 | c.1862dup p.N621Kfs*2 | Frame Shift Ins (INS) | VAF 11/92 reads (12%) | called by mutect2, pindel, varscan2
- OR52R1 | c.817dup p.R273Pfs*9 | Frame Shift Ins (INS) | VAF 14/162 reads (9%) | called by mutect2, pindel
- OTUD5 | c.773_775del p.F258del | In Frame Del (DEL) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.846del p.F282Lfs*8 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- PGAP4 | c.748_749del p.R250Afs*40 | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | called by pindel, varscan2
- PITPNM2 | c.2474dup p.A826Cfs*10 | Frame Shift Ins (INS) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- PPOX | c.1082del p.P361Lfs*5 | Frame Shift Del (DEL) | VAF 7/82 reads (9%) | called by mutect2, pindel
- PRAMEF17 | c.773A>G p.D258G | Missense Mutation (SNP) | VAF 67/469 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PRIMPOL | c.658del p.S220Qfs*47 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- PRX | c.4176del p.Q1393Rfs*25 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- PSD2 | c.247dup p.L83Pfs*37 | Frame Shift Ins (INS) | VAF 19/139 reads (14%) | called by mutect2, pindel, varscan2
- RAB30 | c.278del p.C93Lfs*15 | Frame Shift Del (DEL) | VAF 11/107 reads (10%) | called by mutect2, pindel, varscan2
- RARG | c.939_961delinsTTTGCTGG p.F314_L321delinsLLV | In Frame Del (DEL) | VAF 4/35 reads (11%) | called by pindel, varscan2*
- RBM26 | c.1043del p.P348Hfs*11 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- RFX2 | c.553dup p.S185Kfs*22 | Frame Shift Ins (INS) | VAF 49/180 reads (27%) | called by pindel, varscan2
- RPL4 | c.1199del p.K400Rfs*37 | Frame Shift Del (DEL) | VAF 10/73 reads (14%) | called by mutect2, pindel, varscan2
- SEMA5B | c.926A>G p.D309G | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- SH2B1 | c.1423del p.R475Afs*68 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- SLC6A8 | c.760del p.V254Sfs*54 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- SLCO1B1 | c.1777del p.A593Lfs*2 | Frame Shift Del (DEL) | VAF 17/107 reads (16%) | called by mutect2, pindel, varscan2
- SPATA6 | c.614dup p.N205Kfs*24 | Frame Shift Ins (INS) | VAF 24/126 reads (19%) | called by mutect2, pindel, varscan2
- SPOUT1 | c.129dup p.L44Tfs*68 | Frame Shift Ins (INS) | VAF 10/117 reads (9%) | called by mutect2, pindel
- STK10 | c.1576del p.T526Pfs*15 | Frame Shift Del (DEL) | VAF 57/186 reads (31%) | called by mutect2, pindel, varscan2
- TAF1B | c.195_197del p.K65del | In Frame Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, varscan2
- TAF7L | c.719del p.K240Rfs*26 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | called by mutect2, varscan2
- TBC1D9B | c.3392dup p.S1132Qfs*14 (on ENST00000356834 / NM_198868.3; = p.S1115Qfs*14 on NM_015043.4) | Frame Shift Ins (INS) | VAF 33/134 reads (25%) | called by mutect2, pindel, varscan2
- TCF3 | c.1857dup p.R620Tfs*82 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by mutect2, pindel
- TEX13B | c.425_426del p.E142Afs*41 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by pindel, varscan2
- THSD1 | c.766dup p.V256Gfs*36 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel
- TLE6 | c.1313dup p.P439Sfs*103 (on ENST00000246112 / NM_001143986.2; = p.P316Sfs*103 on NM_024760.3) | Frame Shift Ins (INS) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- TM9SF4 | c.295_297del p.K99del | In Frame Del (DEL) | VAF 16/110 reads (15%) | called by pindel, varscan2
- TMPRSS6 | c.2310del p.L771Wfs*23 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- TSPAN18 | c.332del p.N111Ifs*32 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | called by mutect2, pindel, varscan2
- TSPEAR | c.199del p.R67Afs*3 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel, varscan2
- TTC14 | c.1870del p.S624Pfs*28 | Frame Shift Del (DEL) | VAF 20/118 reads (17%) | called by mutect2, pindel, varscan2
- UIMC1 | c.1246_1247del p.V416Tfs*12 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- USP30 | c.1463_1465del p.E488del | In Frame Del (DEL) | VAF 9/57 reads (16%) | called by pindel, varscan2
- VARS2 | c.1495del p.A499Pfs*41 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- VPS13D | c.9418dup p.S3140Kfs*26 | Frame Shift Ins (INS) | VAF 29/93 reads (31%) | called by mutect2, pindel, varscan2
- VSIG1 | c.488_489del p.S163Cfs*13 | Frame Shift Del (DEL) | VAF 40/94 reads (43%) | called by pindel, varscan2
- WASHC2A | c.3834dup p.E1279Rfs*14 | Frame Shift Ins (INS) | VAF 11/102 reads (11%) | called by mutect2, pindel, varscan2
- WASHC4 | c.2879_2881del p.E960del | In Frame Del (DEL) | VAF 8/72 reads (11%) | called by pindel, varscan2
- WNK2 | c.2409del p.I804Sfs*35 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel, varscan2
- XRN1 | c.4831del p.R1611Gfs*34 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel
- ZC3H4 | c.512del p.P171Hfs*54 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel
- ZNF227 | c.2058del p.K686Nfs*16 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
- ZNF609 | c.2640del p.P882Lfs*30 | Frame Shift Del (DEL) | VAF 17/90 reads (19%) | called by mutect2, pindel, varscan2
- ZNF800 | c.1688dup p.P564Afs*3 | Frame Shift Ins (INS) | VAF 8/81 reads (10%) | called by mutect2, pindel
- ADAM23 | c.2148G>A p.P716= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as rs750323915, COSV52216245, COSV52216476; called by muse, mutect2, varscan2
- ADD3 | c.945A>G p.L315= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as COSV99523060; called by muse, mutect2, varscan2
- ADGRL3 | c.3198A>G p.S1066= (on ENST00000506720 / NM_001322402.2; = p.S998= on NM_015236.6) | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV101546715; called by muse, mutect2, varscan2
- AK4 | c.483T>C p.D161= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV100519710; called by muse, mutect2, varscan2
- AMDHD2 | c.675C>T p.S225= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs375441896; called by muse, mutect2, varscan2
- APOB | c.4356A>G p.L1452= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV99262685; called by muse, mutect2, varscan2
- ASPN | c.1095T>G p.R365= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV100978528; called by muse, mutect2, varscan2
- ATP8B4 | c.2397A>G p.V799= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs951709707, COSV99462700; called by muse, mutect2, varscan2
- AUTS2 | c.2979T>C p.P993= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100714566; called by muse, mutect2
- BEND2 | c.1521C>T p.C507= | Silent (SNP) | VAF 55/193 reads (28%) | catalogued as COSV101191657; called by muse, mutect2, varscan2
- BICD1 | c.1197A>G p.S399= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99861795; called by muse, mutect2, varscan2
- BIRC6 | c.1095T>C p.N365= | Silent (SNP) | VAF 41/110 reads (37%) | catalogued as COSV101427713; called by muse, mutect2, varscan2
- C1orf216 | c.450T>C p.A150= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as rs772179865, COSV99230062; called by muse, mutect2, varscan2
- CAMK1D | c.849A>G p.T283= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV101123327; called by muse, mutect2
- CAP1 | c.351C>A p.T117= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV100471694; called by muse, mutect2, varscan2
- CCDC40 | c.1734C>A p.A578= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100884209; called by muse, mutect2, varscan2
- CDHR5 | c.699G>A p.R233= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100848500; called by muse, mutect2, varscan2
- CHPF2 | c.1663C>A p.R555= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs139831103, COSV99222641; called by muse, mutect2, varscan2
- CHRNG | c.298C>T p.L100= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99285419; called by muse, mutect2, varscan2
- CIT | c.4974C>T p.D1658= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs377318034; called by muse, mutect2, varscan2
- CNTNAP1 | c.390G>A p.S130= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV52851772; called by muse, mutect2, varscan2
- COL4A4 | c.3804T>C p.P1268= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100305843; called by mutect2, varscan2
- CPSF1 | c.2748C>T p.G916= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as rs782350591, COSV58233964; called by muse, mutect2, varscan2
- CSMD2 | c.2274G>A p.S758= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs773732681, COSV53933598; called by muse, mutect2, varscan2
- CUZD1 | c.1674G>A p.A558= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as rs150722442, COSV100158523; called by muse, mutect2, varscan2
- DCAF12L2 | c.966T>G p.A322= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100758393; called by muse, mutect2, varscan2
- DGKH | c.3168G>A p.A1056= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs781121134, COSV99818071; called by muse, mutect2, varscan2
- DIP2A | c.2172T>C p.P724= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100594940; called by muse, mutect2, varscan2
- DISP3 | c.3999G>A p.T1333= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs777322447, COSV99606934; called by muse, mutect2, varscan2
- DLX5 | c.144C>T p.Y48= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV99756119; called by muse, mutect2, varscan2
- DLX6 | c.735G>A p.S245= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs760073542, COSV99142177; called by muse, mutect2
- DNAJC13 | c.6252A>G p.R2084= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV99606269; called by muse, mutect2, varscan2
- DOT1L | c.2931C>T p.T977= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs762151259, COSV67107968; called by muse, mutect2, varscan2
- DPYSL5 | c.189C>T p.I63= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV99981514, COSV99981534; called by muse, mutect2, varscan2
- ECT2 | c.525T>C p.S175= (on ENST00000392692 / NM_001349098.2; = p.S144= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99220708; called by muse, mutect2, varscan2
- ELN | c.453A>G p.P151= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99332030; called by muse, mutect2
- EP400 | c.108G>A p.P36= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs767249896, COSV57772242; called by muse, mutect2
- EPHA5 | c.756T>C p.S252= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99894820; called by muse, mutect2
- FAM214A | c.1107G>A p.E369= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99957463; called by muse, mutect2, varscan2
- FAT1 | c.2031T>C p.T677= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV101498576; called by muse, mutect2, varscan2
- FER1L6 | c.3702A>G p.G1234= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV67548414; called by muse, mutect2, varscan2
- FLG2 | c.783A>G p.Q261= | Silent (SNP) | VAF 22/139 reads (16%) | catalogued as rs775884386, COSV101165521; called by muse, mutect2, varscan2
- FMNL1 | c.2100C>A p.A700= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV58954930; called by muse, mutect2, varscan2
- FOXP1 | c.2001C>T p.Y667= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs772162873, COSV100560506; called by muse, mutect2, varscan2
- FTSJ3 | c.1386C>T p.D462= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs754388735, COSV100834797; called by muse, mutect2, varscan2
- FUS | c.669C>T p.G223= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs767226101, COSV54215211; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR78 | c.384C>A p.G128= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV66763488; called by muse, mutect2, varscan2
- GPRIN3 | c.495G>A p.E165= | Silent (SNP) | VAF 19/160 reads (12%) | catalogued as COSV100310465; called by muse, mutect2, varscan2
- GTPBP6 | c.948C>T p.G316= | Silent (SNP) | VAF 35/172 reads (20%) | catalogued as rs375499069, COSV100397564, COSV58205567; called by muse, mutect2, varscan2
- ICE1 | c.2310A>G p.S770= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs1299052305, COSV99663107; called by muse, mutect2, varscan2
- IGSF21 | c.1146G>T p.G382= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV52125921; called by muse, mutect2, varscan2
- IGSF6 | c.129T>A p.T43= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV99193604; called by muse, mutect2, varscan2
- IKZF3 | c.927T>C p.N309= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs1282824893, COSV99499021; called by muse, mutect2, varscan2
- ILVBL | c.408T>C p.A136= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV99654479; called by muse, mutect2
- ITGA7 | c.939G>A p.S313= (on ENST00000555728; = p.S269= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs199699185, COSV57692672, COSV57697361; called by muse, mutect2, varscan2
- ITGAD | c.498T>C p.F166= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs746480837, COSV101210218; called by muse, mutect2, varscan2
- JCAD | c.1044G>A p.S348= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as rs558801103, COSV64758825; called by muse, mutect2, varscan2
- JSRP1 | c.234G>A p.T78= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as rs760088902, COSV55558322; called by muse, mutect2, varscan2
- KALRN | c.7518T>C p.G2506= (on ENST00000360013 / NM_001024660.4; = p.G809= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV99360665; called by muse, mutect2, varscan2
- KIAA1109 | c.6879A>T p.L2293= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV99145304; called by muse, mutect2, varscan2
- KIAA1549 | c.4653C>T p.D1551= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs575482000, COSV54317476; called by muse, mutect2
- KIRREL3 | c.1434C>T p.G478= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs761423720, COSV69385615; called by mutect2, varscan2
- KRT7 | c.549A>G p.E183= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV100081227; called by muse, mutect2, varscan2
- LDLRAD4 | c.432G>A p.P144= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs200439389; called by muse, mutect2, varscan2
- LRP1B | c.7206A>G p.K2402= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV101249276; called by muse, mutect2, varscan2
- LRP1B | c.951T>C p.C317= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV101249282; called by muse, mutect2, varscan2
- LRP4 | c.3768T>C p.Y1256= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV101066061; called by muse, mutect2, varscan2
- LRRC14 | c.474T>C p.P158= | Silent (SNP) | VAF 18/125 reads (14%) | catalogued as COSV99466830; called by muse, mutect2, varscan2
- LRRIQ4 | c.1461T>C p.C487= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs1263457540, COSV100540001, COSV61619654; called by muse, mutect2, varscan2
- LYSMD4 | c.438C>A p.T146= (on ENST00000409796 / NM_001284417.2; = p.T147= on NM_152449.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/122 reads (32%) | catalogued as COSV100230433; called by muse, mutect2, varscan2
- LYST | c.4608T>C p.C1536= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV101087687; called by muse, mutect2, varscan2
- LZTS3 | c.1035C>T p.S345= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1479677930, COSV100232067; called by muse, mutect2
- MAGEA1 | c.159T>C p.D53= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs1556944097, COSV100756597; called by muse, mutect2, varscan2
- MAP3K15 | c.3423T>C p.P1141= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100133786; called by muse, mutect2
- MAS1 | c.150T>C p.N50= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as rs747019196, COSV99396733; called by muse, mutect2, varscan2
- MAT2B | c.894C>G p.S298= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99796482; called by muse, mutect2, varscan2
- MCM3AP | c.3288T>C p.C1096= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99386297; called by muse, mutect2
- MEAF6 | c.255T>C p.A85= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as COSV99952542; called by muse, mutect2, varscan2
- MINAR1 | c.294C>T p.G98= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs138901860; called by muse, mutect2, varscan2
- MMP21 | c.723C>A p.A241= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100916655; called by muse, mutect2
- MTHFD1 | c.1615A>C p.R539= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV99386450; called by muse, mutect2
- MUC16 | c.12057C>T p.D4019= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs778816991, COSV67489689; called by muse, mutect2, varscan2
- MUC16 | c.10779T>C p.T3593= | Silent (SNP) | VAF 5/85 reads (6%) | catalogued as COSV101197268; called by muse, mutect2
- MYH8 | c.2667C>T p.D889= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs201350664, COSV101238029; called by muse, mutect2, varscan2
- MYNN | c.1359T>G p.A453= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100581680; called by muse, mutect2, varscan2
- NAT9 | c.69T>C p.H23= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs369150541; called by muse, mutect2, varscan2
- NBEA | c.5421T>G p.T1807= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100075422; called by muse, mutect2, varscan2
- NEUROD1 | c.639C>A p.S213= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV99716727; called by muse, mutect2, varscan2
- NOTCH1 | c.4296C>T p.F1432= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs774697636, COSV99483920; ClinVar: likely benign; called by muse, mutect2, varscan2
- NR4A1 | c.930T>C p.P310= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV99670909; called by muse, mutect2, varscan2
- NRIP1 | c.861G>A p.T287= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs768366141, COSV100011978; called by muse, mutect2, varscan2
- NSD1 | c.1452A>G p.E484= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as rs1237773288, COSV61770956; called by muse, mutect2
- OR4C15 | c.1005C>T p.L335= (on ENST00000314644; = p.L281= on NM_001001920.2) | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as rs748710839, COSV58950967, COSV58951059; called by muse, mutect2, varscan2
- OR51F1 | c.912A>G p.K304= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV100598589; called by muse, mutect2, varscan2
- OR51S1 | c.264A>G p.T88= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV100437310; called by muse, mutect2, varscan2
- OR52D1 | c.366C>G p.A122= | Silent (SNP) | VAF 23/170 reads (14%) | catalogued as rs1470966666, COSV100495077; called by muse, mutect2, varscan2
- OVCH1 | c.2523T>G p.S841= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100548158, COSV100548237; called by muse, mutect2
- P4HA2 | c.1350T>C p.R450= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV99386680; called by muse, mutect2
- P4HA2 | c.978C>A p.P326= | Silent (SNP) | VAF 24/205 reads (12%) | catalogued as COSV99386682; called by muse, mutect2, varscan2
- PABPC4 | c.1362C>T p.R454= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100790827; called by muse, mutect2, varscan2
- PARM1 | c.399C>T p.G133= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as rs369237779; called by muse, mutect2, varscan2
- PCDH11X | c.1818G>A p.T606= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs1220720223, COSV53506014; called by muse, mutect2, varscan2
- PCDHA12 | c.1785C>T p.R595= | Silent (SNP) | VAF 27/142 reads (19%) | catalogued as COSV56496982; called by muse, mutect2, varscan2
- PCDHB2 | c.346T>C p.L116= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99522658; called by muse, mutect2, varscan2
- PCNX3 | c.3102G>A p.P1034= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs781064157, COSV100855840; called by muse, mutect2
- PDIA6 | c.738C>T p.G246= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs779374855, COSV55350090; called by muse, mutect2, varscan2
- PHKG2 | c.612T>C p.D204= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs748454786, COSV100079280; called by muse, mutect2, varscan2
- PILRA | c.231C>T p.H77= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as rs756778819, COSV99546216; called by muse, mutect2, varscan2
- PIWIL4 | c.897G>A p.G299= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs1263428611, COSV100132979; called by muse, mutect2, varscan2
- PKDREJ | c.4491T>C p.V1497= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV99478233; called by muse, mutect2
- PLA1A | c.105C>T p.C35= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as rs753943074, COSV56330859; called by muse, mutect2, varscan2
- PLEC | c.13389C>A p.T4463= (on ENST00000322810 / NM_201380.4; = p.T4353= on NM_000445.5) | Silent (SNP) | VAF 9/121 reads (7%) | catalogued as COSV100508942; called by muse, mutect2
- PNMA8B | c.582C>T p.A194= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as rs1392250913, COSV66537934; called by muse, mutect2
- PODXL | c.837C>A p.T279= (on ENST00000378555 / NM_001018111.3; = p.T247= on NM_005397.4) | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV100539051; called by muse, mutect2, varscan2
- POLR1A | c.2781G>A p.P927= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as rs554697621, COSV99806915; called by muse, mutect2, varscan2
- PUM1 | c.1221T>C p.Y407= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as rs1021533714, COSV99927300; called by muse, mutect2, varscan2
- RB1CC1 | c.1311T>C p.C437= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV50251227, COSV99204870; called by muse, mutect2
- RBM38 | c.636C>A p.P212= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100654706; called by muse, mutect2
- RBMXL1 | c.390T>C p.D130= | Silent (SNP) | VAF 21/163 reads (13%) | catalogued as rs1315829481; called by muse, mutect2, varscan2
- RECQL5 | c.1995G>A p.P665= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs768340637, COSV58638147; called by mutect2, varscan2
- RELL2 | c.418A>C p.R140= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99781088; called by muse, mutect2, varscan2
- REV3L | c.2379A>G p.A793= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV100724687; called by muse, mutect2, varscan2
- RIMS2 | c.3012A>T p.L1004= (on ENST00000666250 / NM_001348490.2; = p.L812= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV99153307; called by muse, mutect2, varscan2
- RSBN1L | c.1755T>C p.A585= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV100615834; called by muse, mutect2, varscan2
- SACS | c.11892C>A p.L3964= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV101207105; called by muse, mutect2, varscan2
- SERPINB2 | c.558T>C p.P186= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV100208054; called by muse, mutect2, varscan2
- SF3B3 | c.1896T>G p.A632= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV100209473; called by muse, mutect2, varscan2
- SFPQ | c.1716T>C p.R572= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV100599225; called by muse, mutect2, varscan2
- SINHCAF | c.36T>C p.S12= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV100530423; called by muse, mutect2, varscan2
- SIPA1L1 | c.3132A>G p.P1044= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as rs1259037211, COSV100664950; called by muse, mutect2, varscan2
- SIPA1L3 | c.1422G>A p.S474= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs780595487, COSV55927864, COSV99726768; called by mutect2, varscan2
- SLC18A3 | c.942G>A p.T314= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as rs374372621, COSV60331755; called by muse, mutect2, varscan2
- SLC22A25 | c.1443C>T p.A481= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as COSV100123341; called by muse, mutect2
- SLC2A14 | c.1194G>A p.V398= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100533382; called by muse, mutect2, varscan2
- SPARC | c.705C>T p.F235= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs755476160, COSV50559776; called by muse, mutect2, varscan2
- SPATA46 | c.147T>G p.A49= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV100722695; called by muse, mutect2, varscan2
- SSTR2 | c.549C>A p.L183= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100191928; called by muse, mutect2, varscan2
- STX11 | c.375G>A p.A125= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV62448586; called by muse, mutect2, varscan2
- STX4 | c.663C>T p.H221= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs1380023669, COSV100572880; called by muse, mutect2
- SYNE1 | c.22416A>G p.L7472= (on ENST00000367255 / NM_182961.4; = p.L7401= on NM_033071.3) | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV99548969; called by muse, mutect2, varscan2
- TACC2 | c.9T>C p.N3= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100551170; called by muse, mutect2
- TBC1D24 | c.327C>T p.R109= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs754551693, COSV99564544; ClinVar: likely benign; called by muse, mutect2, varscan2
- TBL1X | c.1509G>A p.K503= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99481872; called by muse, mutect2, varscan2
- THSD7B | c.1041C>A p.P347= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV55701469; called by muse, mutect2, varscan2
- TIAL1 | c.1074A>G p.V358= | Silent (SNP) | VAF 29/130 reads (22%) | catalogued as COSV100958397; called by muse, mutect2, varscan2
- TMC2 | c.1422C>T p.I474= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as COSV62649488; called by muse, mutect2, varscan2
- TMEM117 | c.1119A>G p.T373= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs377158697; called by muse, mutect2, varscan2
- TMPRSS15 | c.1293T>C p.G431= | Silent (SNP) | VAF 26/149 reads (17%) | catalogued as COSV99516357; called by muse, mutect2, varscan2
- TPCN1 | c.360G>A p.L120= | Silent (SNP) | VAF 41/266 reads (15%) | catalogued as COSV100136294; called by muse, varscan2
- TRAF1 | c.147C>T p.G49= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV100875091; called by muse, mutect2, varscan2
- TRIM9 | c.1092A>C p.T364= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100030182; called by muse, mutect2, varscan2
- TSPOAP1 | c.3795A>G p.E1265= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs962966785, COSV52118696; called by muse, mutect2, varscan2
- TTLL5 | c.2964T>G p.S988= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100088346; called by muse, mutect2, varscan2
- TTN | c.98253A>G p.P32751= (on ENST00000591111; = p.P25327= on NM_003319.4) | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs759740681, COSV100588009; called by muse, mutect2, varscan2
- TTN | c.63960G>T p.G21320= (on ENST00000591111; = p.G13896= on NM_003319.4) | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100588011; called by muse, mutect2, varscan2
- TUT7 | c.4464G>A p.A1488= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs764476074, COSV52894844; called by muse, mutect2, varscan2
- TXNRD2 | c.1065C>T p.Y355= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs377072227; called by muse, mutect2, varscan2
- UNC5D | c.1167C>T p.A389= | Silent (SNP) | VAF 9/208 reads (4%) | catalogued as rs1298445990, COSV54825952; called by muse, mutect2
- VASH2 | c.750G>A p.L250= (on ENST00000517399 / NM_001301056.2; = p.L206= on NM_024749.5) | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV99663251; called by muse, mutect2, varscan2
- VCAN | c.1395C>T p.G465= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs772684866, COSV54102683; called by muse, mutect2, varscan2
- VEGFC | c.105A>G p.G35= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99709193; called by muse, mutect2, varscan2
- VPS36 | c.927C>T p.G309= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs199529310, COSV65199326; called by muse, mutect2, varscan2
- WASHC5 | c.1575C>A p.A525= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100572354, COSV59199455; called by muse, mutect2, varscan2
- WDR49 | c.576C>T p.N192= (on ENST00000308378 / NM_001366158.1; = p.N533= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs372277287; called by muse, mutect2, varscan2
- WNK1 | c.1146T>C p.S382= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV100265782; called by muse, mutect2, varscan2
- XRN2 | c.2841C>T p.Y947= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs1414068468, COSV101017838; called by muse, mutect2, varscan2
- ZADH2 | c.750A>T p.G250= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV100463190; called by muse, mutect2, varscan2
- ZBTB20 | c.1314A>G p.E438= (on ENST00000474710 / NM_001164342.2; = p.E365= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV100612333; called by muse, mutect2
- ZFP64 | c.867C>T p.C289= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs771173936, COSV53797770; called by muse, mutect2, varscan2
- ZNF226 | c.2112T>C p.C704= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV100334973; called by muse, mutect2, varscan2
- ZNF48 | c.699C>T p.S233= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs766787192, COSV100197974; called by muse, mutect2, varscan2
- AKAP1 | c.*5dup | 3'UTR (INS) | VAF 7/51 reads (14%) | catalogued as rs769667510; called by mutect2, pindel, varscan2
- AL109984.1 | n.186+1568C>A | Intron (SNP) | VAF 12/64 reads (19%) | catalogued as rs374976001, COSV100800668; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825362 A>G | 5'Flank (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826245 del T | 3'Flank (DEL) | VAF 18/68 reads (26%) | catalogued as rs768711387; called by mutect2, varscan2
- CSF2RA | c.*36G>A | 3'UTR (SNP) | VAF 42/252 reads (17%) | catalogued as rs144367097, COSV62625342; called by muse, mutect2, varscan2
- DOK3 | c.-74G>A | 5'UTR (SNP) | VAF 23/46 reads (50%) | catalogued as COSV100394143; called by muse, mutect2, varscan2
- EI24P4 | n.1002T>C | RNA (SNP) | VAF 27/157 reads (17%) | called by muse, mutect2, varscan2
- FAM153CP | n.402A>T | RNA (SNP) | VAF 25/164 reads (15%) | catalogued as COSV101228621; called by muse, mutect2, varscan2
- HMGB1P1 | n.337del | RNA (DEL) | VAF 12/111 reads (11%) | called by mutect2, pindel, varscan2
- LRRC23 | c.*112del | 3'UTR (DEL) | VAF 32/124 reads (26%) | called by mutect2, varscan2
- MIR1205 | n.17T>C | RNA (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- OR4K17 | c.-12A>G | 5'UTR (SNP) | VAF 20/81 reads (25%) | catalogued as rs762238496, COSV100210393; called by muse, mutect2, varscan2
- PDE4B | c.635-102G>A | Intron (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100301613, COSV58477912; called by muse, mutect2, varscan2
- POM121 | chr7:72948688 A>G | 3'Flank (SNP) | VAF 18/71 reads (25%) | catalogued as rs1554503951, COSV99987305; called by muse, mutect2, varscan2
- RHBG | chr1:156367750 A>G | 5'Flank (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- SSPOP | n.15648T>C | RNA (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100946868; called by muse, mutect2, varscan2
- TTN | c.10361-3858C>T | Intron (SNP) | VAF 45/88 reads (51%) | catalogued as COSV100588013; called by muse, mutect2, varscan2
- UPF2 | c.*210del | 3'UTR (DEL) | VAF 12/46 reads (26%) | called by mutect2, varscan2
- ZDHHC23 | c.1041-545T>C | Intron (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100361990; called by muse, mutect2, varscan2
